Somatic mutation profile of tumor specimen 0DXMMB from CCDI case PBCRTV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.6 years (572 days).
Specimen 0DXMMB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b9d0d08-838f-4933-ba28-0bbc8183f8b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXMLR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c69240b7-fcb1-40f1-bd1b-5aea1bfc0a64

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNK1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 327/868 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs199630093, COSV64034520; called by muse, mutect2, varscan2
- MACF1 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 334/868 reads (38%) | catalogued as rs62623398; called by muse, varscan2
- MSH6 | c.2765G>A p.R922Q | Missense Mutation (SNP) | VAF 284/742 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs752839086, CD103558, COSV52283392, COSV52283657; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RIF1 | c.3581C>T p.S1194F | Missense Mutation (SNP) | VAF 48/1275 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV54621055; called by muse, mutect2
- OR8S1 | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 64/615 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- C10orf71 | c.2568G>A p.T856= | Silent (SNP) | VAF 240/571 reads (42%) | catalogued as rs746121240; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 45/1361 reads (3%) | called by muse, mutect2
- AC114498.2 | chr1:629959 G>A | 3'Flank (SNP) | VAF 134/751 reads (18%) | catalogued as rs574456121; called by muse, mutect2, varscan2
- DMRTB1 | c.577+24G>A | Intron (SNP) | VAF 34/304 reads (11%) | catalogued as rs1431231832; called by muse, varscan2
